Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A3JP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A3JP-01A (Primary Tumor).

[page 1 of 3]
ICD--0-3

Carcinoma, serous, NOS 8441/3
Site: endometrium C54.1

lw
12/11/11

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Uterus, bilateral ovaries and fallopian tubes, hysterectomy and bilateral salpingo-oophorectomy: FIGO grade III (of III) endometrial adenocarcinoma, serous adenocarcinoma, is identified forming a mass (4.4 x 2.6 x 0.7 cm) involving a polyp (5.4 x 5.3 x 1.2 cm) attached to the fundus of the endometrial cavity. The tumor is confined to the polyp. The tumor does not involve the endocervix. Lymphovascular space invasion is not identified. The margins are negative for tumor. There are multiple (2 subserosal, 2.1 cm and 4.7 cm in greatest dimension; 8 intramural, ranging in size from 0.4 cm to 1.8 cm in greatest dimension; 12 submucosal, ranging in size from 0.3 cm to 6.0 cm in greatest dimension) leiomyomata in the myometrium. The bilateral ovaries and fallopian tubes are not involved.
- B. Lymph nodes, left pelvic, dissection: Multiple (31) lymph nodes are negative for tumor.
- C. Lymph nodes, right pelvic, dissection: Multiple (25) lymph nodes are negative for tumor.
- D. Lymph nodes, right para-aortic, excision: Multiple (12) lymph nodes are negative for tumor.
- E. Gonadal vessel, right, excision: Negative for tumor.
- F. Mesentery, transverse colon, excision: Fat necrosis with dystrophic calcifications forming a 1.0 x 0.8 x 0.6 cm nodule.
- G. Omentum, omentectomy: Benign omentum. Multiple (4) omental lymph nodes are negative for tumor.
- H. Lymph nodes, left para-aortic, excision: Multiple (6) lymph nodes are negative for tumor.
- I. Gonadal vessel, left, excision: Negative for tumor.
- J. Appendix, appendectomy: Unremarkable appendix.
- K. Peritoneum, cul-de-sac, staging biopsy: Negative for tumor. Frozen section histologic interpretation performed by:
- L. Peritoneum, bladder, staging biopsy: Negative for tumor. Frozen section histologic interpretation performed by
- M. Peritoneum, left colic gutter, staging biopsy: Negative for tumor. Frozen section histologic interpretation performed by:
- N. Peritoneum, right colic gutter, staging biopsy: Negative for tumor. Frozen section histologic interpretation performed by:
- O. Peritoneum, left pelvic sidewall, staging biopsy: Negative for tumor. Frozen section histologic interpretation performed by:
- P. Peritoneum, right pelvic sidewall, staging biopsy: Negative for tumor. Frozen section histologic interpretation performed by:
- Q. Peritoneum, right diaphragm, staging biopsy: Negative for tumor. Frozen section histologic interpretation performed by:

with available surgical material, [AJCC pT1aN0] (7th edition, 2010).

[page 2 of 3]
This final pathology report is based on the gross/macrosopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

A. Received fresh labeled "uterus, left and right fallopian tubes and ovaries" is a 250.0 gram uterus with attached bilateral fallopian tubes and ovaries. The uterine serosa is smooth. There is a 5.4 x 5.3 x 1.2 cm polyp in the fundus of the endometrial cavity. The polyp has a 1.5 x 0.8 cm area of attachment and no invasion grossly. The surface of the polyp shows a 4.4 x 2.6 x 0.7 cm irregular nodular mass. The myometrial thickness is 2.0 cm. There are multiple (2 subserosal, 2.1 cm and 4.7 cm in greatest dimension; 8 intramural, ranging in size from 0.4 cm to 1.8 cm in greatest dimension; 12 submucosal, ranging in size from 0.3 cm to 6.0 cm in greatest dimension) leiomyomata in the myometrium. There is a 1.8 x 0.9 x 0.8 cm right ovary with a smooth outer surface and a solid cut surface with a 4.5 x 0.4 cm right fallopian tube, which is unremarkable. There is a 2.2 x 0.9 x 0.9 cm left ovary with a smooth outer surface and a solid cut surface with a 4.0 x 0.4 cm left fallopian tube, which is unremarkable. Representative sections are submitted.

B. Received fresh labeled "left pelvic lymph nodes" is a 5.7 x 3.5 x 1.3 cm aggregate of adipose and lymphatic tissue. Multiple (33) lymph nodes are identified. All lymph nodes submitted.

C. Received fresh labeled "right pelvic lymph nodes" is a 6.0 x 4.7 x 1.4 cm aggregate of adipose and lymphatic tissue. Multiple (27) lymph nodes are identified. All lymph nodes submitted.

D. Received fresh labeled "right para-aortic lymph nodes" is a 2.6 x 1.9 x 0.8 cm aggregate of adipose and lymphatic tissue. Multiple (14) lymph nodes are identified. All lymph nodes submitted.
Grossed by .

E. Received fresh labeled "right gonadal vessels" is a 5.2 cm in length by 0.5 cm in diameter portion of unremarkable blood vessel. Representative sections are submitted.

F. Received fresh labeled "transverse mesentery nodule" is a 1.0 x 0.8 x 0.6 cm yellow calcified nodule, favor fat necrosis. All submitted.

G. Received fresh labeled "omentum" is a 26.3 x 21.4 x 1.4 cm portion of omentum. No masses are identified grossly. Multiple (4) omental lymph nodes are identified. Representative sections are submitted.

H. Received fresh labeled "left para-aortic lymph nodes" is a 3.8 x 1.5 x 1.3 cm aggregate of adipose and lymphatic tissue. Multiple (8) lymph nodes are identified. All lymph nodes submitted.

I. Received fresh labeled "left gonadal vessels" is a 3.8 cm in length by 0.5 cm in diameter portion of unremarkable blood vessel. Representative sections are submitted.

J. Received fresh labeled "appendix" is a 6.1 x 0.6 cm appendix with smooth serosa. There is no gross perforation. Representative sections are submitted.

K. Received fresh labeled "cul-de-sac" is a 0.8 x 0.5 x 0.5 cm portion of yellow soft tissue, which is entirely submitted.

L. Received fresh labeled "bladder peritoneum" is a 1.0 x 0.7 x 0.5

[page 3 of 3]
cm portion of yellow soft tissue, which is entirely submitted.

M. Received fresh labeled "left colic gutter" is a 0.7 x 0.6 x 0.4 cm portion of yellow soft tissue, which is entirely submitted.

N. Received fresh labeled "right colic gutter" is a 1.1 x 0.7 x 0.3 cm portion of yellow soft tissue, which is entirely submitted.

O. Received fresh labeled "left pelvic sidewall" is a 0.8 x 0.7 x 0.4 cm portion of yellow soft tissue, which is entirely submitted.

P. Received fresh labeled "right pelvic sidewall" is a 0.9 x 0.5 x 0.4 cm portion of yellow soft tissue, which is entirely submitted.

Q. Received fresh labeled "right diaphragm" is a 0.5 x 0.4 x 0.4 cm portion of yellow soft tissue, which is entirely submitted.

HIIPAA Discrepancy		

Source: NCI Genomic Data Commons file 170355ae-09e0-401e-94d9-8e9cf6de0b67 (TCGA-D1-A3JP.62290E86-409F-4590-AA2C-D3D2F77148FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).